Somatic mutation profile of tumor specimen TCGA-43-6143-01A (aliquot TCGA-43-6143-01A-11D-1817-08) from TCGA case TCGA-43-6143, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 70.7 years (25,820 days).
Specimen TCGA-43-6143-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bdc58f9c-1158-43e8-9823-b920de4aeb88.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-43-6143-10A (Blood Derived Normal), aliquot TCGA-43-6143-10A-01D-1817-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a59c44e-be52-46c6-9a4c-9553bbdc7c6d

The open-access MAF lists 335 somatic variants for this specimen: 256 protein-altering or splice-affecting, 72 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 214, Silent 72, Nonsense Mutation 18, Frame Shift Del 11, Splice Site 9, Intron 4, Frame Shift Ins 2, RNA 2, Translation Start Site 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.641A>G p.H214R | Missense Mutation (SNP) | VAF 22/31 reads (71%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1057519992, CM103210, COSV52670202, COSV52732998, COSV52834506, COSV52887765; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC10 | c.755A>T p.H252L (on ENST00000372530 / NM_001198934.2; = p.H209L on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV55090973; called by muse, mutect2, varscan2
- ACTA1 | c.367C>A p.Q123K | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.026); catalogued as COSV64203919, COSV64204156; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1283T>C p.L428P | Missense Mutation (SNP) | VAF 57/65 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV56476294; called by muse, mutect2, varscan2
- ADAMTS12 | c.3542G>T p.R1181I | Missense Mutation (SNP) | VAF 92/216 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV61269755; called by muse, mutect2, varscan2
- ADAMTS12 | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 39/68 reads (57%) | catalogued as COSV61256271; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1995A>T p.Q665H | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV54457710; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1996G>T p.E666* | Nonsense Mutation (SNP) | VAF 24/65 reads (37%) | catalogued as COSV54457725; called by muse, mutect2, varscan2
- ADCY8 | c.3051C>G p.D1017E | Missense Mutation (SNP) | VAF 122/223 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV53916820; called by muse, mutect2, varscan2
- ADGRA3 | c.1195A>G p.R399G | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV51565633; called by muse, mutect2, varscan2
- ADGRV1 | c.9262G>C p.E3088Q | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs931062858, COSV67990068; called by muse, mutect2
- ADSL | c.607G>T p.G203C | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53408804; called by muse, mutect2, varscan2
- AFAP1L1 | c.1993C>G p.L665V | Missense Mutation (SNP) | VAF 66/130 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.401); catalogued as COSV57046463; called by muse, mutect2, varscan2
- AHSG | c.851G>A p.G284D | Missense Mutation (SNP) | VAF 42/316 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as COSV56608495, COSV56608697; called by muse, mutect2, varscan2
- AJAP1 | c.1229C>G p.S410C | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65450477, COSV65452098; called by muse, mutect2, varscan2
- AK5 | c.1424G>A p.R475H (on ENST00000354567 / NM_174858.3; = p.R449H on NM_012093.4) | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as rs769633875, COSV60977121; called by muse, mutect2, varscan2
- AL592490.1 | c.2491G>T p.E831* | Nonsense Mutation (SNP) | VAF 96/107 reads (90%) | catalogued as COSV69427001; called by muse, mutect2, varscan2
- AL645922.1 | c.3511G>A p.V1171I | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.151); catalogued as COSV64888192; called by muse, mutect2
- ALDH1L1 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.02); catalogued as rs370745999; called by muse, mutect2
- ANK2 | c.10789C>G p.Q3597E | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.99); catalogued as COSV52174195; called by muse, mutect2, varscan2
- ANO8 | c.3212G>C p.G1071A | Missense Mutation (SNP) | VAF 66/81 reads (81%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.026); catalogued as COSV50187122; called by muse, mutect2, varscan2
- ANTXR2 | c.717A>T p.L239F | Missense Mutation (SNP) | VAF 51/73 reads (70%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as COSV55019825; called by muse, mutect2, varscan2
- APBB2 | c.1135C>T p.P379S (on ENST00000295974 / NM_001166050.2; = p.P380S on NM_004307.2) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.493); catalogued as COSV55957115; called by muse, mutect2, varscan2
- ARHGEF1 | c.2534A>G p.N845S | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782293753, COSV61528691; called by muse, mutect2, varscan2
- ARMC4 | c.2798C>A p.T933K | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as COSV100536371, COSV59468234; called by muse, mutect2, varscan2
- ARPP21 | c.713T>C p.L238S | Missense Mutation (SNP) | VAF 83/104 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV51802608; called by muse, mutect2, varscan2
- ASAH2 | c.208A>T p.T70S | Missense Mutation (SNP) | VAF 52/85 reads (61%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as COSV61484053; called by muse, mutect2, varscan2
- ASTN2 | c.1196G>T p.G399V (on ENST00000313400 / NM_001365069.1; = p.G348V on NM_014010.5) | Missense Mutation (SNP) | VAF 28/33 reads (85%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.994); catalogued as COSV57796659; called by muse, mutect2, varscan2
- ASXL1 | c.565+1G>A p.X189_splice | Splice Site (SNP) | VAF 17/89 reads (19%) | catalogued as COSV60114081, COSV60121190; called by muse, mutect2, varscan2
- ATP23 | c.517G>C p.G173R | Missense Mutation (SNP) | VAF 45/54 reads (83%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); catalogued as COSV55686355; called by muse, mutect2, varscan2
- ATP8B2 | c.2174C>T p.T725M (on ENST00000672630; = p.T692M on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 106/263 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs367934414; called by muse, mutect2, varscan2
- BPI | c.946-1G>C p.X316_splice (on ENST00000262865; = p.X312_splice on NM_001725.3) | Splice Site (SNP) | VAF 79/114 reads (69%) | catalogued as COSV53404272, COSV53406895; called by muse, mutect2, varscan2
- BRINP1 | c.1527G>C p.E509D | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT tolerated (1); PolyPhen possibly damaging (0.899); catalogued as COSV56292600, COSV56306264, COSV99774078; called by muse, mutect2, varscan2
- C12orf40 | c.443G>A p.C148Y | Missense Mutation (SNP) | VAF 37/41 reads (90%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1566626863, COSV61135093; called by muse, mutect2, varscan2
- C1QTNF6 | c.720C>A p.Y240* | Nonsense Mutation (SNP) | VAF 19/27 reads (70%) | catalogued as COSV55396814; called by muse, mutect2, varscan2
- C7 | c.1160G>T p.G387V | Missense Mutation (SNP) | VAF 83/215 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as COSV57477178; called by muse, mutect2
- CACNA1A | c.3215T>A p.M1072K | Missense Mutation (SNP) | VAF 33/40 reads (83%) | SIFT tolerated (0.23); PolyPhen benign (0.048); catalogued as COSV64204518; called by muse, mutect2, varscan2
- CACNA2D2 | c.2708A>G p.N903S (on ENST00000479441 / NM_001174051.3; = p.N896S on NM_006030.4) | Missense Mutation (SNP) | VAF 97/125 reads (78%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); catalogued as COSV56566197; called by muse, varscan2
- CCDC190 | c.25C>A p.Q9K | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as rs371986435; called by muse, mutect2, varscan2
- CCDC27 | c.318+2T>C p.X106_splice | Splice Site (SNP) | VAF 8/22 reads (36%) | catalogued as rs149388135; called by muse, mutect2
- CCDC83 | c.350G>T p.R117L | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.593); catalogued as COSV54700993, COSV54703567; called by muse, mutect2, varscan2
- CCDC83 | c.962A>G p.H321R (on ENST00000342404 / NM_001286159.2; = p.H352R on NM_173556.5) | Missense Mutation (SNP) | VAF 140/262 reads (53%) | SIFT tolerated (0.6); PolyPhen benign (0.053); catalogued as rs763064890, COSV54703573; called by muse, mutect2, varscan2
- CCDC91 | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.176); catalogued as COSV60345150, COSV60350364; called by muse, mutect2, varscan2
- CCT6A | c.671G>A p.R224K | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV51906749; called by muse, mutect2, varscan2
- CD163 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 65/89 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63135060; called by muse, mutect2, varscan2
- CDC14A | c.138A>T p.E46D | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV60560462; called by muse, mutect2, varscan2
- CDC73 | c.1451G>T p.R484L | Missense Mutation (SNP) | VAF 42/69 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as COSV66468525, COSV66470907; called by muse, mutect2, varscan2
- CDCP2 | c.146T>C p.L49P | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.137); catalogued as COSV61284756; called by muse, mutect2, varscan2
- CDH10 | c.586G>C p.A196P | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52588361, COSV52595598; called by muse, mutect2, varscan2
- CDH2 | c.1262G>C p.R421T | Missense Mutation (SNP) | VAF 97/180 reads (54%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.506); catalogued as COSV52287809, COSV52292857; called by muse, mutect2, varscan2
- CDK5RAP2 | c.5551C>G p.R1851G | Missense Mutation (SNP) | VAF 46/60 reads (77%) | SIFT tolerated (0.32); PolyPhen benign (0.019); catalogued as COSV62576233; called by muse, mutect2, varscan2
- CELSR2 | c.6256G>T p.A2086S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.113); catalogued as COSV54775886; called by muse, mutect2, varscan2
- CENPC | c.461T>C p.L154S | Missense Mutation (SNP) | VAF 62/114 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV56624714; called by muse, mutect2, varscan2
- CEP120 | c.223A>T p.I75F | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV60266838; called by muse, mutect2, varscan2
- CEP162 | c.935A>C p.E312A | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.359); catalogued as COSV57621833; called by muse, mutect2, varscan2
- CFHR5 | c.548G>T p.G183V | Missense Mutation (SNP) | VAF 145/308 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56823886, COSV56824510; called by muse, mutect2, varscan2
- CHD7 | c.6804T>A p.F2268L | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.931); catalogued as COSV71112749; called by muse, mutect2, varscan2
- CHEK1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 72/163 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54024670; called by muse, mutect2, varscan2
- CHST2 | c.751G>T p.G251C | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58886251; called by muse, mutect2, varscan2
- CLMN | c.148A>C p.N50H | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV54184999; called by muse, varscan2
- CMYA5 | c.1975G>C p.E659Q | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV71407611; called by muse, mutect2, varscan2
- CNGA2 | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 46/51 reads (90%) | catalogued as COSV61705354; called by muse, mutect2, varscan2
- CNTNAP2 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.896); catalogued as COSV62190285, COSV62217924; called by muse, mutect2, varscan2
- COX6B1 | c.206G>T p.W69L | Missense Mutation (SNP) | VAF 86/146 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55838107; called by muse, mutect2, varscan2
- CR1 | c.1006G>T p.A336S (on ENST00000367051; = p.A786S on NM_000651.6) | Missense Mutation (SNP) | VAF 113/308 reads (37%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.57); catalogued as COSV100887382; called by muse, mutect2, varscan2
- CSMD2 | c.8086C>G p.R2696G | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs752189179, COSV53930605, COSV53933751; called by muse, mutect2, varscan2
- CTTNBP2 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 86/268 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.377); catalogued as COSV50424631; called by muse, mutect2, varscan2
- DCAF4L2 | c.485C>A p.S162* | Nonsense Mutation (SNP) | VAF 79/130 reads (61%) | catalogued as rs748853957, COSV100150629, COSV60480352; called by muse, mutect2, varscan2
- DKK1 | c.332G>T p.C111F | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64760542; called by muse, varscan2
- DPPA4 | c.431C>G p.S144* | Nonsense Mutation (SNP) | VAF 64/133 reads (48%) | catalogued as COSV100169492, COSV59511624, COSV59512548; called by muse, mutect2, varscan2
- DPRX | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 70/213 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV64949797; called by muse, mutect2, varscan2
- DROSHA | c.1090C>A p.R364S | Missense Mutation (SNP) | VAF 102/250 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as COSV60773172, COSV60779169; called by muse, mutect2, varscan2
- DYSF | c.5172G>T p.Q1724H | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.139); catalogued as COSV50477149; called by muse, mutect2, varscan2
- EFCAB6 | c.3750G>T p.M1250I | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV53067453; called by muse, mutect2, varscan2
- EFHC1 | c.227A>G p.Q76R | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV64136994; called by muse, mutect2, varscan2
- EHD3 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 50/81 reads (62%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs769119216, COSV59031053; called by muse, mutect2, varscan2
- ELAPOR2 | c.2565C>G p.C855W (on ENST00000450689 / NM_001142749.3; = p.C688W on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51888888; called by muse, mutect2, varscan2
- ELMO1 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV60313554; called by muse, mutect2, varscan2
- EPHB1 | c.1919T>A p.L640Q | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.923); catalogued as COSV67656072; called by muse, mutect2, varscan2
- ERICH3 | c.4046C>T p.T1349M | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV58612352; called by muse, mutect2, varscan2
- FAM117A | c.224A>G p.E75G | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV53632904; called by muse, mutect2, varscan2
- FAM71A | c.120C>A p.F40L | Missense Mutation (SNP) | VAF 119/168 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54236330; called by muse, mutect2, varscan2
- FAT2 | c.11459T>G p.L3820R | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV55824507; called by muse, mutect2, varscan2
- FBN2 | c.1190G>C p.G397A | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52504665, COSV52528362; called by muse, mutect2, varscan2
- FBXO22 | c.1183G>T p.A395S | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV57618114, COSV57619241; called by muse, mutect2, varscan2
- FCAR | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 161/328 reads (49%) | SIFT tolerated (0.99); PolyPhen benign (0.005); catalogued as rs762426689, COSV100629194, COSV62030693; called by muse, mutect2, varscan2
- FCHSD1 | c.1762T>C p.W588R | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51838012; called by muse, mutect2, varscan2
- FCRLA | c.152C>A p.A51D (on ENST00000367959; = p.A28D on NM_032738.4) | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV52686963; called by muse, mutect2, varscan2
- FGD5 | c.3182C>T p.S1061F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53247132; called by muse, mutect2, varscan2
- FIGLA | c.247C>A p.R83S | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.093); catalogued as rs369140654, CM1514382, COSV100189644; called by muse, mutect2, varscan2
- FRG2B | c.48G>T p.Q16H | Missense Mutation (SNP) | VAF 22/440 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.264); catalogued as COSV71043309; called by muse, mutect2
- FSD2 | c.671A>G p.E224G | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV58011288; called by muse, mutect2, varscan2
- FTSJ3 | c.400+2T>C p.X134_splice | Splice Site (SNP) | VAF 46/72 reads (64%) | catalogued as COSV59563164; called by muse, mutect2, varscan2
- GABRA4 | c.1438G>C p.G480R | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV51931376; called by muse, mutect2, varscan2
- GABRE | c.962C>T p.T321I | Missense Mutation (SNP) | VAF 47/56 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV64820425; called by muse, mutect2, varscan2
- GABRG2 | c.1293G>T p.M431I (on ENST00000361925 / NM_001375343.1; = p.M391I on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.899); catalogued as COSV62720039; called by muse, mutect2, varscan2
- GLRA4 | c.1057del p.R353Efs*53 | Frame Shift Del (DEL) | VAF 42/60 reads (70%) | catalogued as COSV60327431; called by mutect2, pindel, varscan2
- GP2 | c.1339A>G p.M447V (on ENST00000381362 / NM_001007240.3; = p.M444V on NM_001502.4) | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.393); catalogued as COSV56895284; called by muse, mutect2, varscan2
- GPR17 | c.868T>A p.Y290N | Missense Mutation (SNP) | VAF 35/40 reads (88%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.478); catalogued as COSV55756239; called by muse, mutect2, varscan2
- GRK2 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.463); catalogued as rs71640262, COSV57952835; called by muse, mutect2
- HERC1 | c.1327C>T p.Q443* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as rs774088719, COSV71248938; called by muse, mutect2, varscan2
- HIF3A | c.1922C>A p.P641H (on ENST00000377670 / NM_152795.4; = p.P572H on NM_022462.4) | Missense Mutation (SNP) | VAF 88/172 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.667); catalogued as COSV54977285; called by muse, mutect2, varscan2
- HUWE1 | c.9203A>G p.D3068G | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.559); catalogued as COSV53355107; called by muse, varscan2
- IRX1 | c.491C>A p.A164D | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57360882; called by muse, mutect2, varscan2
- ITGB4 | c.3663C>A p.S1221R | Missense Mutation (SNP) | VAF 72/136 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774118950, COSV52329504; called by muse, mutect2, varscan2
- KAT2B | c.275A>G p.E92G | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.497); catalogued as COSV55431867; called by muse, mutect2, varscan2
- KAT8 | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 35/94 reads (37%) | catalogued as COSV54897934, COSV99571706; called by muse, mutect2, varscan2
- KEAP1 | c.1516A>G p.I506V | Missense Mutation (SNP) | VAF 44/50 reads (88%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV50393304; called by muse, mutect2, varscan2
- KIF14 | c.3323A>G p.Y1108C | Missense Mutation (SNP) | VAF 116/167 reads (69%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as rs1398242938, COSV66262697; called by muse, mutect2, varscan2
- KIR2DL3 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 83/254 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV60899092; called by muse, mutect2, varscan2
- KL | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 217/246 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66309381, COSV66309399; called by muse, mutect2, varscan2
- KLF7 | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 117/127 reads (92%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58745091; called by muse, mutect2, varscan2
- KMT2C | c.9278C>T p.T3093I | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV51467794; called by muse, mutect2, varscan2
- LAMA2 | c.1677C>A p.D559E | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.04); catalogued as COSV101370446, COSV70351821; called by muse, mutect2, varscan2
- LAMA4 | c.3841G>A p.V1281M (on ENST00000230538 / NM_001105206.3; = p.V1274M on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as rs184696189, COSV57901140; called by muse, mutect2, varscan2
- LCOR | c.3614G>T p.R1205L | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs778649685, COSV53716308, COSV53717168; called by muse, mutect2, varscan2
- LEPR | c.191A>T p.Y64F | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0.265); catalogued as COSV60759215; called by muse, mutect2, varscan2
- LGR5 | c.800A>G p.N267S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57007375; called by muse, mutect2, varscan2
- LRRC55 | c.691C>G p.P231A | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT tolerated (0.79); PolyPhen benign (0.024); catalogued as rs377055442; called by muse, mutect2, varscan2
- LRRN2 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 138/312 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs769194983, COSV65783417; called by muse, varscan2
- LSM14B | c.313G>T p.A105S | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV53382127; called by muse, mutect2, varscan2
- MAML2 | c.1457G>A p.G486D | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.024); catalogued as COSV73264147; called by muse, mutect2, varscan2
- MAN2A2 | c.1197-2A>T p.X399_splice | Splice Site (SNP) | VAF 45/69 reads (65%) | catalogued as COSV64639035; called by muse, mutect2, varscan2
- MAP4 | c.1367C>G p.T456S | Missense Mutation (SNP) | VAF 52/59 reads (88%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV64242566; called by muse, mutect2, varscan2
- MAP7 | c.2216G>T p.G739V | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV63421338; called by muse, mutect2, varscan2
- MBD5 | c.2171G>A p.G724E | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.21); catalogued as COSV68698262; called by muse, mutect2, varscan2
- MINDY4 | c.1629G>T p.L543F | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as rs751960716, COSV54676118; called by muse, varscan2
- MKX | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65392646; called by muse, mutect2, varscan2
- MLF1 | c.728T>C p.I243T | Missense Mutation (SNP) | VAF 75/100 reads (75%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.343); catalogued as COSV63034608; called by muse, mutect2, varscan2
- MS4A14 | c.2029C>A p.L677M | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.048); catalogued as COSV100280019; called by muse, mutect2, varscan2
- MYH15 | c.5821A>G p.K1941E | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.164); catalogued as rs200773679, COSV56305346, COSV56314786; called by muse, mutect2, varscan2
- MYT1L | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV67726048; called by muse, mutect2, varscan2
- NCAM2 | c.885C>G p.F295L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.025); catalogued as COSV53083631, COSV53088373; called by muse, mutect2, varscan2
- NCAM2 | c.2438C>A p.A813D | Missense Mutation (SNP) | VAF 76/119 reads (64%) | SIFT tolerated (0.59); PolyPhen benign (0.057); catalogued as rs759603682, COSV53088384, COSV53103799; called by muse, mutect2, varscan2
- NES | c.4773G>T p.W1591C | Missense Mutation (SNP) | VAF 89/153 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV63961820; called by muse, mutect2, varscan2
- NEUROG3 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.162); catalogued as COSV54343160; called by muse, mutect2, varscan2
- NLRP3 | c.2600A>T p.D867V | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60228346; called by muse, mutect2, varscan2
- NOD1 | c.2161C>T p.R721W | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs371304122; called by muse, mutect2, varscan2
- NVL | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV55874209, COSV55874965; called by muse, mutect2, varscan2
- OR10V1 | c.722C>A p.T241N | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55699553, COSV55702118; called by muse, mutect2, varscan2
- OR11H1 | c.189G>A p.M63I | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs751452467; called by mutect2, varscan2
- OR14I1 | c.213C>A p.Y71* | Nonsense Mutation (SNP) | VAF 37/59 reads (63%) | catalogued as COSV61200307; called by muse, mutect2, varscan2
- OR2G6 | c.794G>A p.R265K | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs779699113, COSV58575203; called by muse, mutect2, varscan2
- OR2L2 | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 157/227 reads (69%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV63551749; called by muse, mutect2, varscan2
- OR2T3 | c.542G>C p.S181T | Missense Mutation (SNP) | VAF 167/244 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV62082899; called by muse, mutect2, varscan2
- OR2T34 | c.258G>T p.M86I | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as COSV60901479; called by muse, mutect2, varscan2
- OR4C13 | c.900T>A p.C300* | Nonsense Mutation (SNP) | VAF 24/31 reads (77%) | catalogued as COSV73648824; called by muse, mutect2, varscan2
- OR4C6 | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.112); catalogued as COSV58603134, COSV58603870, COSV58604215; called by mutect2, varscan2
- OR4D11 | c.694G>C p.G232R | Missense Mutation (SNP) | VAF 53/241 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV57586358; called by muse, mutect2, varscan2
- OR4K5 | c.923C>A p.P308Q | Missense Mutation (SNP) | VAF 55/207 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.163); catalogued as COSV60004273; called by muse, mutect2, varscan2
- OR4M1 | c.869C>A p.T290K | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV60062507; called by muse, mutect2, varscan2
- OR52J3 | c.530C>A p.A177D | Missense Mutation (SNP) | VAF 64/75 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV66747382; called by muse, mutect2
- OR56A4 | c.461T>A p.L154H | Missense Mutation (SNP) | VAF 33/47 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV58111119; called by muse, mutect2, varscan2
- OR5H1 | c.528C>G p.H176Q | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV63402903; called by muse, mutect2, varscan2
- OR7A10 | c.272T>A p.V91D | Missense Mutation (SNP) | VAF 69/80 reads (86%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.09); catalogued as COSV50166553; called by muse, mutect2, varscan2
- P2RY14 | c.337G>C p.G113R | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56386987; called by muse, mutect2, varscan2
- PCDHA5 | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.224); catalogued as rs1381844487, COSV65352049; called by muse, mutect2, varscan2
- PCDHA7 | c.1094C>A p.P365Q | Missense Mutation (SNP) | VAF 74/229 reads (32%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.163); catalogued as COSV65344200; called by muse, mutect2, varscan2
- PCIF1 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as COSV65026740; called by muse, mutect2, varscan2
- PDGFC | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV56844615; called by muse, mutect2, varscan2
- PFKL | c.1048G>T p.E350* | Nonsense Mutation (SNP) | VAF 42/57 reads (74%) | catalogued as COSV62464331; called by muse, mutect2, varscan2
- PHKB | c.2113G>T p.A705S | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.053); catalogued as COSV54527190; called by muse, mutect2, varscan2
- PKD1L2 | c.2839A>G p.R947G | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV55165504; called by muse, mutect2, varscan2
- PLA2G3 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.04); catalogued as COSV53210944; called by muse, mutect2
- PLPP4 | c.512G>T p.S171I | Missense Mutation (SNP) | VAF 63/108 reads (58%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV64828749; called by muse, mutect2, varscan2
- PLRG1 | c.436A>G p.S146G | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV57424152; called by muse, mutect2, varscan2
- PNPLA8 | c.110A>G p.H37R | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.015); catalogued as rs752242396, COSV57553717; called by muse, mutect2, varscan2
- POTEE | c.2076G>T p.K692N | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100386800, COSV100386928; called by muse, mutect2, varscan2
- PPP1R13L | c.655G>T p.G219W | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as rs777898158, COSV62909094, COSV62909118; called by muse, mutect2, varscan2
- PRG2 | c.567G>T p.Q189H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.738); catalogued as COSV61293849; called by muse, mutect2, varscan2
- PSG8 | c.698T>G p.L233R | Missense Mutation (SNP) | VAF 229/529 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1302014848, COSV60613577; called by muse, mutect2, varscan2
- PTPRO | c.2363C>A p.A788D | Missense Mutation (SNP) | VAF 152/174 reads (87%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV55516009; called by muse, mutect2, varscan2
- RAPGEF2 | c.2731G>T p.A911S | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.027); catalogued as COSV52430934; called by muse, mutect2, varscan2
- RASSF7 | c.868T>A p.C290S | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV60347694; called by muse, mutect2, varscan2
- REG3G | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 61/247 reads (25%) | catalogued as COSV55450530, COSV55450570; called by muse, mutect2, varscan2
- RELN | c.6575G>A p.R2192Q | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.271); catalogued as COSV58985727; called by muse, mutect2, varscan2
- RGS5 | c.481C>A p.L161M | Missense Mutation (SNP) | VAF 107/218 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58353479; called by muse, mutect2, varscan2
- RHEX | c.454A>T p.S152C | Missense Mutation (SNP) | VAF 68/88 reads (77%) | SIFT deleterious (0); PolyPhen benign (0.208); catalogued as COSV58981035; called by muse, mutect2, varscan2
- RHOJ | c.562G>C p.D188H | Missense Mutation (SNP) | VAF 97/179 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57459874; called by muse, mutect2, varscan2
- RIMS1 | c.1016C>A p.A339E | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1161600600, COSV53468352, COSV53490515; called by muse, mutect2
- RMDN1 | c.396C>A p.S132R | Missense Mutation (SNP) | VAF 61/112 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.353); catalogued as COSV52208142; called by muse, mutect2, varscan2
- RPRD2 | c.3294G>T p.M1098I | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV64821943; called by muse, mutect2, varscan2
- RTN1 | c.2231C>A p.A744E | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV50733646; called by muse, mutect2, varscan2
- RUNDC3B | c.806G>T p.C269F | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.459); catalogued as rs758189339, COSV56695110; called by muse, mutect2, varscan2
- RXRG | c.92C>A p.A31E | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.062); catalogued as COSV63232581; called by muse, mutect2, varscan2
- RYR3 | c.5683G>T p.E1895* | Nonsense Mutation (SNP) | VAF 38/90 reads (42%) | catalogued as COSV66800318; called by muse, mutect2, varscan2
- RYR3 | c.5684A>G p.E1895G | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as COSV66800323; called by muse, mutect2, varscan2
- SAFB | c.2334+1G>T p.X778_splice | Splice Site (SNP) | VAF 57/61 reads (93%) | catalogued as COSV52652572; called by muse, varscan2
- SCGB1D1 | c.250A>G p.I84V | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.165); catalogued as COSV60377823; called by muse, mutect2, varscan2
- SCN7A | c.1381A>C p.K461Q | Missense Mutation (SNP) | VAF 111/125 reads (89%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV69273106; called by muse, mutect2, varscan2
- SEMA5B | c.2483G>A p.G828D | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as COSV52102972; called by muse, mutect2, varscan2
- SFI1 | c.3032G>T p.R1011L (on ENST00000400288 / NM_001007467.3; = p.R980L on NM_014775.4) | Missense Mutation (SNP) | VAF 77/132 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV56718094; called by muse, mutect2, varscan2
- SH2B1 | c.382G>T p.D128Y | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV59464925; called by muse, mutect2, varscan2
- SIK3 | c.1430T>C p.L477P (on ENST00000445177 / NM_001366686.2; = p.L483P on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/136 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.377); catalogued as COSV52618794; called by muse, mutect2, varscan2
- SLC4A3 | c.448G>T p.A150S | Missense Mutation (SNP) | VAF 31/34 reads (91%) | SIFT tolerated (0.86); PolyPhen benign (0.039); catalogued as COSV56095656; called by muse, mutect2, varscan2
- SLC5A4 | c.329T>C p.L110P | Missense Mutation (SNP) | VAF 79/197 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs1202056656, COSV56672111; called by muse, mutect2, varscan2
- SLC6A13 | c.512C>G p.S171C | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.153); catalogued as COSV100569929, COSV58258392; called by muse, mutect2, varscan2
- SMARCA1 | c.2818-2A>C p.X940_splice | Splice Site (SNP) | VAF 41/48 reads (85%) | catalogued as COSV64412832; called by muse, mutect2, varscan2
- SMO | c.625G>T p.D209Y | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV50827048, COSV50834248; called by muse, mutect2, varscan2
- SOGA3 | c.1978C>T p.R660W | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64107575; called by muse, mutect2, varscan2
- SORCS3 | c.2891G>T p.S964I | Missense Mutation (SNP) | VAF 61/127 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV63796640; called by muse, mutect2, varscan2
- SORCS3 | c.3381G>A p.M1127I | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.459); catalogued as rs778909054, COSV63816848; called by muse, mutect2, varscan2
- SOS1 | c.1336A>T p.M446L | Missense Mutation (SNP) | VAF 66/209 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV67676440; called by muse, mutect2, varscan2
- SP140 | c.1987C>T p.P663S | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.169); catalogued as COSV59447545; called by muse, mutect2, varscan2
- SRRM2 | c.5873C>G p.S1958C | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57073536, COSV57077003; called by muse, mutect2, varscan2
- SYNE1 | c.12722A>G p.D4241G (on ENST00000367255 / NM_182961.4; = p.D4170G on NM_033071.3) | Missense Mutation (SNP) | VAF 5/125 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as COSV55035804; called by muse, mutect2
- SYNJ2 | c.1603G>T p.G535W | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62898955; called by muse, mutect2, varscan2
- TAS2R3 | c.932A>G p.K311R | Missense Mutation (SNP) | VAF 78/128 reads (61%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.502); catalogued as rs768391312, COSV56092201; called by muse, mutect2, varscan2
- TECRL | c.911C>T p.T304I | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1482167418, COSV67088726; called by muse, mutect2, varscan2
- TENM1 | c.7723T>C p.F2575L | Missense Mutation (SNP) | VAF 72/81 reads (89%) | SIFT tolerated (0.07); PolyPhen benign (0.263); catalogued as COSV64437307; called by muse, mutect2, varscan2
- TEX15 | c.6982G>A p.D2328N (on ENST00000256246; = p.D2711N on NM_001350162.2) | Missense Mutation (SNP) | VAF 62/81 reads (77%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56343906; called by muse, mutect2, varscan2
- TEX15 | c.2205C>G p.S735R (on ENST00000256246; = p.S1118R on NM_001350162.2) | Missense Mutation (SNP) | VAF 47/62 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV56349721; called by muse, mutect2, varscan2
- TG | c.1634A>G p.N545S | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.03); catalogued as COSV55085360; called by muse, mutect2, varscan2
- TJAP1 | c.11C>G p.A4G | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV52502292; called by muse, mutect2, varscan2
- TJP1 | c.1373A>T p.K458M | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV62043943; called by muse, mutect2, varscan2
- TMEM106C | c.70G>T p.G24C | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV56743129; called by muse, mutect2, varscan2
- TNFRSF17 | c.317A>C p.K106T | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as COSV50001409; called by muse, mutect2, varscan2
- TPR | c.2943G>C p.Q981H | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs772315608, COSV66603053; called by muse, mutect2, varscan2
- TRA2A | c.421C>G p.R141G | Missense Mutation (SNP) | VAF 43/64 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV51716262, COSV51717793; called by muse, mutect2, varscan2
- TRIM48 | c.58G>C p.G20R | Missense Mutation (SNP) | VAF 188/196 reads (96%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV70161958, COSV70162436, COSV70163489; called by muse, mutect2, varscan2
- TRIM58 | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 29/91 reads (32%) | catalogued as COSV63571373; called by muse, mutect2, varscan2
- TSPAN15 | c.735G>T p.Q245H | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64783529; called by muse, mutect2, varscan2
- TTC14 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 13/98 reads (13%) | catalogued as COSV56012859; called by muse, mutect2, varscan2
- TTC14 | c.167A>T p.E56V | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.502); catalogued as COSV56012881; called by muse, mutect2, varscan2
- TTLL2 | c.1106T>A p.L369H | Missense Mutation (SNP) | VAF 99/251 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53444869; called by muse, mutect2, varscan2
- TTN | c.35509G>C p.E11837Q (on ENST00000591111; = p.E10910Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | PolyPhen benign (0.201); catalogued as COSV100628729, COSV60189535; called by muse, mutect2, varscan2
- URGCP | c.377A>G p.N126S (on ENST00000453200 / NM_001077663.3; = p.N117S on NM_017920.4) | Missense Mutation (SNP) | VAF 63/131 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs1002832860, COSV56249846; called by muse, mutect2, varscan2
- USP29 | c.1024T>C p.C342R | Missense Mutation (SNP) | VAF 104/199 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as COSV54144517; called by muse, mutect2, varscan2
- WDR7 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54358107; called by muse, mutect2
- ZBBX | c.1773T>A p.Y591* | Nonsense Mutation (SNP) | VAF 61/351 reads (17%) | catalogued as COSV56795026; called by muse, mutect2, varscan2
- ZDHHC21 | c.622-1G>C p.X208_splice | Splice Site (SNP) | VAF 5/85 reads (6%) | catalogued as COSV101099390, COSV66614337; called by muse, mutect2
- ZIK1 | c.77G>T p.C26F | Missense Mutation (SNP) | VAF 82/205 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV56737796; called by muse, mutect2, varscan2
- ZMIZ2 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746898806, COSV54809629; called by muse, mutect2, varscan2
- ZMYM1 | c.1536G>T p.K512N | Missense Mutation (SNP) | VAF 9/202 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV63252465, COSV63252586; called by muse, mutect2
- ZNF492 | c.1082G>T p.G361V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV101513937; called by mutect2, varscan2
- ZNF569 | c.2040C>G p.H680Q | Missense Mutation (SNP) | VAF 70/236 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV57597120; called by muse, mutect2, varscan2
- ZNF609 | c.271A>T p.K91* | Nonsense Mutation (SNP) | VAF 55/116 reads (47%) | catalogued as COSV58586765; called by muse, mutect2, varscan2
- ACACA | c.1682G>A p.G561E | Missense Mutation (SNP) | VAF 47/78 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- CACNA1I | c.2247dup p.R750Afs*121 | Frame Shift Ins (INS) | VAF 7/33 reads (21%) | called by mutect2, pindel, varscan2
- FNDC1 | c.1369+1del p.X457_splice | Splice Site (DEL) | VAF 50/147 reads (34%) | called by mutect2, pindel, varscan2
- FRG2C | c.48G>T p.Q16H | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.264); called by muse, mutect2
- GRM1 | c.2379del p.T794Pfs*6 | Frame Shift Del (DEL) | VAF 31/91 reads (34%) | called by mutect2, pindel, varscan2
- IGKV1-12 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2
- INHA | c.682dup p.E228Gfs*126 | Frame Shift Ins (INS) | VAF 43/63 reads (68%) | called by mutect2, pindel, varscan2
- MGA | c.4692del p.T1565Hfs*11 | Frame Shift Del (DEL) | VAF 28/76 reads (37%) | called by mutect2, pindel, varscan2
- NHS | c.766del p.L256Ffs*28 | Frame Shift Del (DEL) | VAF 42/69 reads (61%) | called by mutect2, pindel, varscan2
- RB1 | c.1177_1181del p.D394Tfs*10 | Frame Shift Del (DEL) | VAF 69/92 reads (75%) | called by mutect2, pindel, varscan2
- RYR3 | c.13863del p.L4622Sfs*34 (on ENST00000389232; = p.L4623Sfs*34 on NM_001036.6) | Frame Shift Del (DEL) | VAF 114/307 reads (37%) | called by mutect2, pindel, varscan2
- SLC9C1 | c.3112_3113del p.S1038Yfs*4 | Frame Shift Del (DEL) | VAF 38/106 reads (36%) | called by mutect2, pindel, varscan2
- SPAM1 | c.1112del p.L371Qfs*18 | Frame Shift Del (DEL) | VAF 41/90 reads (46%) | called by mutect2, pindel, varscan2
- TRGV8 | c.175G>T p.G59W | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UGGT2 | c.2664_2678del p.A889_Y893del | In Frame Del (DEL) | VAF 9/57 reads (16%) | called by mutect2, varscan2
- ZFHX4 | c.1115del p.G372Vfs*11 | Frame Shift Del (DEL) | VAF 25/94 reads (27%) | called by mutect2, varscan2
- ZFHX4 | c.1115G>T p.G372V | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.656); called by mutect2, varscan2
- ZMIZ1 | c.1707_1708del p.D570Wfs*35 | Frame Shift Del (DEL) | VAF 19/37 reads (51%) | called by mutect2, pindel, varscan2
- ZMYM3 | c.621del p.T208Pfs*19 | Frame Shift Del (DEL) | VAF 12/19 reads (63%) | called by mutect2, pindel, varscan2
- ADAMTSL4 | c.1008C>A p.G336= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as COSV55003443; called by muse, mutect2, varscan2
- AFAP1 | c.486G>T p.R162= | Silent (SNP) | VAF 33/125 reads (26%) | catalogued as COSV61797112; called by muse, mutect2, varscan2
- ANAPC1 | c.5310C>G p.L1770= | Silent (SNP) | VAF 31/137 reads (23%) | catalogued as COSV61977660; called by muse, mutect2, varscan2
- AOAH | c.375C>G p.L125= | Silent (SNP) | VAF 78/153 reads (51%) | catalogued as COSV51745750; called by muse, mutect2, varscan2
- ASTN1 | c.1461C>G p.G487= | Silent (SNP) | VAF 47/854 reads (6%) | catalogued as COSV99920431; called by muse, mutect2
- BRD4 | c.2803C>T p.L935= | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as COSV54590048; called by muse, mutect2, varscan2
- C1QTNF6 | c.447C>T p.G149= | Silent (SNP) | VAF 39/78 reads (50%) | catalogued as COSV55396838; called by muse, mutect2, varscan2
- C2orf69 | c.594T>C p.S198= | Silent (SNP) | VAF 151/158 reads (96%) | catalogued as COSV60667008; called by muse, mutect2, varscan2
- CACNG3 | c.933C>T p.R311= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV50074953; called by muse, mutect2, varscan2
- CANX | c.468T>C p.N156= | Silent (SNP) | VAF 45/94 reads (48%) | catalogued as COSV56005539; called by muse, mutect2, varscan2
- CCDC22 | c.546G>A p.E182= | Silent (SNP) | VAF 12/13 reads (92%) | catalogued as COSV66109458; called by muse, mutect2, varscan2
- CCT5 | c.15G>T p.G5= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as rs754687206, COSV54724717; called by muse, mutect2, varscan2
- CDH6 | c.1689C>A p.T563= | Silent (SNP) | VAF 50/90 reads (56%) | catalogued as COSV54074103; called by muse, mutect2, varscan2
- CFAP65 | c.3876G>T p.P1292= | Silent (SNP) | VAF 49/53 reads (92%) | catalogued as COSV58563683; called by muse, mutect2, varscan2
- CHRM2 | c.408C>A p.T136= | Silent (SNP) | VAF 33/113 reads (29%) | catalogued as COSV57778332; called by muse, mutect2, varscan2
- CIAO3 | c.102G>A p.A34= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as rs752296998, COSV52403341; called by muse, mutect2, varscan2
- CLDN1 | c.177C>T p.T59= | Silent (SNP) | VAF 181/228 reads (79%) | catalogued as rs756618263, COSV55044509; called by muse, mutect2, varscan2
- CPM | c.1197A>G p.Q399= | Silent (SNP) | VAF 66/70 reads (94%) | catalogued as COSV58034515; called by muse, mutect2, varscan2
- CSMD3 | c.10074T>A p.P3358= (on ENST00000297405 / NM_001363185.1; = p.P3189= on NM_052900.3) | Silent (SNP) | VAF 204/557 reads (37%) | catalogued as COSV52243713; called by muse, mutect2, varscan2
- CST1 | c.156C>A p.I52= | Silent (SNP) | VAF 96/161 reads (60%) | catalogued as COSV59055042, COSV59055804; called by muse, mutect2, varscan2
- DPM2 | c.9G>T p.T3= | Silent (SNP) | VAF 26/32 reads (81%) | catalogued as COSV55948479; called by muse, mutect2, varscan2
- ECD | c.1401C>T p.H467= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as rs1422732185, COSV65900583; called by muse, mutect2, varscan2
- FAM98A | c.1116G>A p.G372= | Silent (SNP) | VAF 18/165 reads (11%) | catalogued as COSV53211041; called by muse, mutect2, varscan2
- FGD5 | c.3183C>T p.S1061= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs546298225, COSV53247149; called by muse, mutect2, varscan2
- GCAT | c.1119C>G p.V373= | Silent (SNP) | VAF 50/125 reads (40%) | catalogued as rs149775052, COSV50649563; called by muse, mutect2, varscan2
- GMIP | c.141A>G p.S47= | Silent (SNP) | VAF 21/24 reads (88%) | catalogued as COSV52288632; called by muse, mutect2, varscan2
- GOLM1 | c.517C>A p.R173= | Silent (SNP) | VAF 75/82 reads (91%) | catalogued as COSV57415366; called by muse, mutect2, varscan2
- GRINA | c.972C>T p.L324= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as rs567920896, COSV100507297, COSV57593122; called by muse, mutect2, varscan2
- HCN1 | c.2343G>A p.R781= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as rs575150344, COSV57502099; called by muse, mutect2, varscan2
- IL1RAPL1 | c.876T>C p.D292= | Silent (SNP) | VAF 4/47 reads (9%) | catalogued as COSV56279637; called by muse, mutect2
- INSIG2 | c.677G>A p.*226= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as COSV55523105; called by muse, mutect2, varscan2
- M1AP | c.1512C>A p.S504= | Silent (SNP) | VAF 94/154 reads (61%) | catalogued as COSV51209945; called by muse, mutect2, varscan2
- MACF1 | c.1815A>T p.R605= | Silent (SNP) | VAF 35/48 reads (73%) | catalogued as COSV58386742; called by muse, mutect2, varscan2
- MECOM | c.1947T>C p.T649= (on ENST00000468789 / NM_001105078.4; = p.T837= on NM_004991.4) | Silent (SNP) | VAF 59/288 reads (20%) | catalogued as COSV52969206; called by muse, mutect2, varscan2
- MUC16 | c.28485C>T p.T9495= | Silent (SNP) | VAF 68/353 reads (19%) | catalogued as COSV67479419; called by muse, mutect2, varscan2
- MYH13 | c.3396C>G p.L1132= | Silent (SNP) | VAF 58/70 reads (83%) | catalogued as COSV52835407, COSV99352673; called by muse, mutect2, varscan2
- MYOM3 | c.4161G>C p.G1387= | Silent (SNP) | VAF 58/81 reads (72%) | catalogued as COSV58390156, COSV58397099; called by muse, mutect2, varscan2
- NUAK2 | c.1707G>T p.R569= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as COSV100903963; called by muse, mutect2, varscan2
- NUP205 | c.2523C>T p.H841= | Silent (SNP) | VAF 36/85 reads (42%) | catalogued as COSV53662726; called by muse, mutect2, varscan2
- OR13F1 | c.213C>A p.I71= | Silent (SNP) | VAF 90/118 reads (76%) | catalogued as COSV58252085; called by muse, mutect2, varscan2
- OR4C6 | c.411G>T p.R137= | Silent (SNP) | VAF 45/113 reads (40%) | catalogued as COSV58605066; called by mutect2, varscan2
- OR5W2 | c.603C>A p.T201= | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as rs755481707, COSV60615068, COSV60617260; called by muse, mutect2, varscan2
- OR9Q2 | c.42T>C p.L14= | Silent (SNP) | VAF 63/141 reads (45%) | catalogued as COSV61112289; called by muse, mutect2, varscan2
- PARP9 | c.1854C>T p.G618= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as COSV64451276; called by muse, mutect2, varscan2
- PCDHGA8 | c.81G>T p.G27= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV53987012; called by muse, mutect2, varscan2
- PHLDB1 | c.1056G>A p.L352= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV61880385; called by muse, mutect2, varscan2
- PIGN | c.996T>A p.I332= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as CM1512190, COSV62950539; called by muse, mutect2
- PPAT | c.414T>C p.H138= | Silent (SNP) | VAF 26/47 reads (55%) | catalogued as COSV51705431; called by muse, mutect2, varscan2
- PPP1R15B | c.351C>T p.A117= | Silent (SNP) | VAF 109/321 reads (34%) | catalogued as COSV65816125; called by muse, mutect2, varscan2
- PREX1 | c.1062C>T p.T354= | Silent (SNP) | VAF 25/116 reads (22%) | catalogued as rs751737707, COSV64254127; called by muse, mutect2, varscan2
- PTCH2 | c.3054C>T p.P1018= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs773222322, COSV64712191; called by muse, mutect2, varscan2
- PTPRO | c.2364C>A p.A788= | Silent (SNP) | VAF 153/175 reads (87%) | catalogued as COSV55516021; called by muse, mutect2, varscan2
- RNF20 | c.2688A>G p.T896= | Silent (SNP) | VAF 132/162 reads (81%) | catalogued as rs1327244606, COSV66661693; called by muse, mutect2, varscan2
- RYR3 | c.6537C>T p.A2179= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV66800326; called by muse, mutect2, varscan2
- SEC14L4 | c.135A>T p.R45= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV55400535; called by muse, mutect2, varscan2
- SGK1 | c.66A>C p.A22= | Silent (SNP) | VAF 40/129 reads (31%) | catalogued as COSV52812639; called by muse, mutect2, varscan2
- SLC4A4 | c.666G>T p.R222= (on ENST00000264485 / NM_001098484.3; = p.R178= on NM_003759.4) | Silent (SNP) | VAF 62/115 reads (54%) | catalogued as rs1157330971, COSV52630408; called by muse, mutect2, varscan2
- SLCO6A1 | c.210C>T p.A70= | Silent (SNP) | VAF 137/301 reads (46%) | catalogued as COSV65812653; called by muse, mutect2, varscan2
- SLIT3 | c.1410C>A p.L470= | Silent (SNP) | VAF 46/98 reads (47%) | catalogued as COSV60621129, COSV60636098; called by muse, mutect2, varscan2
- SOX14 | c.315C>G p.L105= | Silent (SNP) | VAF 42/92 reads (46%) | catalogued as rs781687358, COSV60163192; called by muse, mutect2, varscan2
- SPSB3 | c.684C>T p.H228= | Silent (SNP) | VAF 29/55 reads (53%) | catalogued as rs778523436, COSV51599621; called by muse, mutect2, varscan2
- SYNE1 | c.12135G>T p.L4045= (on ENST00000367255 / NM_182961.4; = p.L3974= on NM_033071.3) | Silent (SNP) | VAF 54/114 reads (47%) | catalogued as COSV55035844; called by muse, varscan2
- TACR3 | c.1161C>A p.L387= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as COSV59204932; called by muse, mutect2, varscan2
- TENM4 | c.5913A>T p.S1971= | Silent (SNP) | VAF 47/93 reads (51%) | catalogued as COSV53647426; called by muse, mutect2, varscan2
- TGFB2 | c.570G>C p.V190= | Silent (SNP) | VAF 58/344 reads (17%) | catalogued as COSV65110161, COSV65111099; called by muse, mutect2, varscan2
- TLN2 | c.3378G>T p.T1126= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV60891486; called by muse, mutect2, varscan2
- TNFSF10 | c.828G>T p.G276= | Silent (SNP) | VAF 108/153 reads (71%) | catalogued as COSV53843832; called by muse, mutect2, varscan2
- TNR | c.915A>G p.G305= | Silent (SNP) | VAF 70/151 reads (46%) | catalogued as COSV54899470; called by muse, mutect2, varscan2
- TTI1 | c.663C>T p.I221= | Silent (SNP) | VAF 22/175 reads (13%) | catalogued as rs1259502528, COSV65062450; called by muse, mutect2, varscan2
- ZNF646 | c.708G>A p.E236= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV56216642; called by muse, mutect2, varscan2
- ZNF786 | c.150T>C p.D50= | Silent (SNP) | VAF 33/61 reads (54%) | catalogued as COSV60277051; called by muse, mutect2, varscan2
- ZNF804B | c.1377G>T p.T459= | Silent (SNP) | VAF 33/104 reads (32%) | catalogued as COSV60839542; called by muse, mutect2, varscan2
- ACP1 | c.231+85G>C | Intron (SNP) | VAF 33/49 reads (67%) | catalogued as COSV55244025; called by muse, mutect2, varscan2
- ACP1 | c.231+86G>T | Intron (SNP) | VAF 33/49 reads (67%) | catalogued as COSV55243941, COSV55244300, COSV55244789; called by muse, mutect2, varscan2
- CFAP46 | c.966+92G>T | Intron (SNP) | VAF 95/143 reads (66%) | catalogued as COSV63952759; called by muse, mutect2, varscan2
- KIR2DL4 | c.*2G>T | 3'UTR (SNP) | VAF 50/106 reads (47%) | called by muse, mutect2, varscan2
- LINC01600 | n.745C>A | RNA (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- PTGER3 | c.*24-12848G>T | Intron (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2, varscan2
- SSPOP | n.14263G>C | RNA (SNP) | VAF 6/29 reads (21%) | catalogued as COSV65133413; called by muse, mutect2, varscan2
